Gene-level copy-number profile of tumor specimen HTMCP-01-06-00136-01A from CGCI case HTMCP-01-06-00136, project CGCI-HTMCP-DLBCL (HIV+ Tumor Molecular Characterization Project - Diffuse Large B-Cell Lymphoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 46.0 years (16,795 days).
Specimen HTMCP-01-06-00136-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9f1fd36f-c1b1-4eda-beab-85934e742a39.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-01-06-00136-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,707 have no estimate.
https://portal.gdc.cancer.gov/files/8a8ee2dd-96fe-44e9-9d24-0f26417aa16e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 128; copy number 1: 789; copy number 2: 44,060; copy number 3: 11,427; copy number 4: 1,051; copy number 5: 191; copy number 6: 1,207; copy number 7: 63.

Homozygous deletions (total copy number 0; autosomes only): 128 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,492,300–3,438,621, 27 genes (within-gene range 0–1): AL139246.1, AL139246.4, PANK4, HES5, AL139246.5, TNFRSF14-AS1, TNFRSF14, AL139246.2, AL139246.3, PRXL2B, MMEL1, MMEL1-AS1, TTC34, AC242022.2, AC242022.1, AL592464.2, AL592464.3, AL592464.1, ACTRT2, PRDM16-DT, PRDM16, MIR4251, AL008733.1, AL512383.1, AL590438.1, AL354743.2, AL354743.1.
- chr2:88,857,161–89,245,596, 38 genes (within-gene range 0–2): IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30.
- chr14:105,851,705–106,122,709, 62 genes (within-gene range 0–1) (broad region; genes not listed).
- chr14:106,170,749–106,171,052, 1 gene (within-gene range 0–1): IGHVIII-16-1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,461 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:116,514,534–116,571,039, 1 gene, copy number 5 (within-gene range 4–5): CD58.
- chr1:116,560,024–121,580,524, 114 genes, copy number 5 (broad region; genes not listed).
- chr5:58,198–45,895,970, 679 genes, copy number 6–7 (broad region; genes not listed).
- chr11:102,347,211–132,404,060, 667 genes, copy number 5–7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 277. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
